Somatic mutation profile of tumor specimen HCM-CSHL-0510-D13-01A (aliquot HCM-CSHL-0510-D13-01A-11D-A82H-36) from HCMI case HCM-CSHL-0510-D13, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubulovillous adenoma, NOS; Tissue or organ of origin: Small intestine, NOS; AJCC pathologic stage: Stage I; Tumor grade: GX; Age at diagnosis: 59.1 years (21,570 days).
Specimen HCM-CSHL-0510-D13-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f60724e-81ba-4486-9c2d-23798cfe6869.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0510-D13-10A (Blood Derived Normal), aliquot HCM-CSHL-0510-D13-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c891e8c-ebc9-4ef8-bed1-276b79d10f86

The open-access MAF lists 167 somatic variants for this specimen: 122 protein-altering or splice-affecting, 39 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 39, Frame Shift Ins 5, Nonsense Mutation 4, Frame Shift Del 2, Intron 2, RNA 2, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 149/287 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRA1 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 201/707 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs779122897, COSV66926538; called by muse, mutect2, varscan2
- ANK3 | c.3241C>T p.R1081* (on ENST00000280772 / NM_001320874.2; = p.R215* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 22/352 reads (6%) | catalogued as rs775324952, COSV55059130; called by muse, mutect2
- APC | c.4391_4394del p.E1464Vfs*8 | Frame Shift Del (DEL) | VAF 136/186 reads (73%) | catalogued as rs387906234; called by mutect2, pindel, varscan2
- ARHGAP17 | c.641C>T p.T214M | Missense Mutation (SNP) | VAF 99/206 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.063); catalogued as rs746155178; called by muse, mutect2, varscan2
- ARID4A | c.2353G>C p.E785Q | Missense Mutation (SNP) | VAF 13/264 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as COSV100793918, COSV100794476; called by muse, mutect2
- AXL | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 257/566 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs138219571; called by muse, mutect2, varscan2
- BPIFC | c.508G>A p.V170I | Missense Mutation (SNP) | VAF 28/352 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.011); catalogued as rs369957427; called by muse, mutect2
- BRINP1 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 243/523 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs987725274, COSV56293277; called by muse, mutect2, varscan2
- BRWD3 | c.2888C>A p.S963* | Nonsense Mutation (SNP) | VAF 101/214 reads (47%) | catalogued as COSV64751280; called by muse, mutect2, varscan2
- CAGE1 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 21/404 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as rs780325334; called by muse, mutect2
- CAMTA1 | c.1991C>T p.T664M | Missense Mutation (SNP) | VAF 351/614 reads (57%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.105); catalogued as rs576226270, COSV57903148, COSV57916355; called by muse, mutect2, varscan2
- CATSPER4 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 261/452 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs781301429; called by muse, mutect2, varscan2
- CD2AP | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 85/269 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); catalogued as rs779860972; called by muse, mutect2, varscan2
- CDH12 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 250/442 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs147080212; called by muse, mutect2, varscan2
- CERKL | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 73/265 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.103); catalogued as rs1180928247, COSV59208345; called by muse, mutect2, varscan2
- CETN1 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 143/479 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV59121768; called by muse, mutect2, varscan2
- CFAP47 | c.7418G>A p.R2473H | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs1388166915; called by muse, mutect2, varscan2
- CLCA4 | c.2362C>T p.R788C | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as rs553556484, COSV100991174; called by muse, mutect2, varscan2
- CNTLN | c.3940G>A p.A1314T | Missense Mutation (SNP) | VAF 66/443 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs772018140, COSV52093696; called by muse, mutect2, varscan2
- CNTN4 | c.2716G>A p.G906R | Missense Mutation (SNP) | VAF 131/325 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.63); catalogued as rs371362562, COSV100639240; called by muse, mutect2, varscan2
- CSNKA2IP | c.1028A>C p.K343T | Missense Mutation (SNP) | VAF 186/420 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1014219433; called by muse, mutect2, varscan2
- CTDP1 | c.2045C>T p.T682M | Missense Mutation (SNP) | VAF 206/609 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867198820; called by muse, mutect2, varscan2
- CWC22 | c.1904G>T p.G635V | Missense Mutation (SNP) | VAF 72/147 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99844131; called by muse, mutect2, varscan2
- DHTKD1 | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 174/517 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs756540722, COSV53802706, COSV99536414; called by muse, varscan2
- EHD3 | c.1210C>T p.R404W | Missense Mutation (SNP) | VAF 43/616 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs183394828; called by muse, mutect2
- EPHB1 | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 265/650 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as rs373293977; called by muse, mutect2, varscan2
- EPM2AIP1 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 98/581 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV51625246; called by muse, mutect2, varscan2
- F2R | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 150/465 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as rs777334197, COSV59930250; called by muse, mutect2, varscan2
- FGA | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 25/398 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs560911144, COSV57395542; called by muse, mutect2
- FRK | c.528dup p.L177Sfs*22 | Frame Shift Ins (INS) | VAF 47/365 reads (13%) | catalogued as rs776966836; called by mutect2, pindel, varscan2
- GABRA6 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 148/264 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs754862222, COSV50877427; called by muse, mutect2, varscan2
- GDF1 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 257/525 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.295); catalogued as rs1438878646; called by muse, mutect2, varscan2
- GPR150 | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 349/660 reads (53%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.954); catalogued as rs1442232469, COSV66168046; called by muse, mutect2, varscan2
- GPR174 | c.918A>C p.Q306H | Missense Mutation (SNP) | VAF 128/491 reads (26%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV99338211; called by muse, mutect2, varscan2
- GTPBP1 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 396/698 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1307294473; called by muse, mutect2, varscan2
- HRAS | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 372/727 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54240340; called by muse, mutect2, varscan2
- IGLON5 | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 98/440 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1362560321; called by muse, mutect2, varscan2
- INSL6 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 81/196 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs767494322, COSV67562518; called by muse, mutect2, varscan2
- KCNT1 | c.569G>A p.R190H (on ENST00000488444; = p.R209H on NM_020822.3) | Missense Mutation (SNP) | VAF 26/652 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs756952430, COSV99705943; ClinVar: uncertain significance; called by muse, mutect2
- KMT2B | c.7715C>T p.T2572M | Missense Mutation (SNP) | VAF 124/343 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as rs867499379, COSV53074231; called by muse, mutect2, varscan2
- LLCFC1 | c.332C>T p.T111M (on ENST00000458732; = p.T80M on NM_178829.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 410/859 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as rs369000744, COSV100787015; called by muse, mutect2, varscan2
- LRP1B | c.2924G>T p.C975F | Missense Mutation (SNP) | VAF 107/330 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67187329; called by muse, mutect2, varscan2
- MTNR1B | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 291/807 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1345298351, COSV57066059; called by muse, mutect2, varscan2
- NCAM1 | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 162/286 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs782485722; called by muse, mutect2, varscan2
- NRXN3 | c.881G>A p.R294H (on ENST00000557594 / NM_001272020.2; = p.R926H on NM_004796.6) | Missense Mutation (SNP) | VAF 204/429 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs144373051; called by muse, mutect2, varscan2
- NWD2 | c.3310G>A p.V1104I | Missense Mutation (SNP) | VAF 134/455 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs775787015, COSV58754013; called by muse, mutect2, varscan2
- OR2M7 | c.796C>A p.H266N | Missense Mutation (SNP) | VAF 119/188 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.191); catalogued as COSV58740004; called by muse, mutect2, varscan2
- PCDH15 | c.4707G>T p.K1569N | Missense Mutation (SNP) | VAF 208/386 reads (54%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV57258622; called by muse, mutect2, varscan2
- PCDHA12 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 58/827 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); catalogued as COSV56496461; called by muse, mutect2
- PCDHA13 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 87/390 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs782044159, COSV56540616; called by muse, mutect2, varscan2
- PCDHB9 | c.77C>A p.A26E | Missense Mutation (SNP) | VAF 264/491 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.856); catalogued as rs782422350; called by muse, mutect2, varscan2
- PCDHGB2 | c.2341G>A p.V781I | Missense Mutation (SNP) | VAF 136/430 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as rs757587046, COSV53894173; called by muse, mutect2, varscan2
- PPP4R3C | c.776T>G p.L259R | Missense Mutation (SNP) | VAF 63/249 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101297303; called by muse, mutect2, varscan2
- RHOXF2 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 214/1088 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.012); catalogued as rs782250177; called by muse, mutect2, varscan2
- SLC25A1 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 221/400 reads (55%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.786); catalogued as rs781963874, COSV53206387; called by muse, mutect2, varscan2
- SLC5A8 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 28/732 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV101610558; called by muse, mutect2
- SOX17 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 463/1512 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.194); catalogued as COSV52024544, COSV52025261; called by muse, mutect2, varscan2
- SPATA31A7 | c.1180G>A p.G394R | Missense Mutation (SNP) | VAF 212/710 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.134); catalogued as rs200244273; called by muse, mutect2, varscan2
- SYNE1 | c.25430C>T p.T8477I (on ENST00000367255 / NM_182961.4; = p.T8429I on NM_033071.3) | Missense Mutation (SNP) | VAF 36/388 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.724); catalogued as rs1394635601; called by muse, mutect2
- TANC2 | c.4684G>A p.V1562M | Missense Mutation (SNP) | VAF 223/436 reads (51%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.495); catalogued as rs368956259, COSV67331062; called by muse, mutect2, varscan2
- TCHHL1 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 139/401 reads (35%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as rs1342896445; called by muse, mutect2, varscan2
- THOC2 | c.941C>T p.T314M | Missense Mutation (SNP) | VAF 179/331 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.28); catalogued as rs761579225; called by muse, mutect2, varscan2
- TMEM259 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 340/856 reads (40%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs201156482, COSV52261519; called by muse, mutect2
- TTN | c.9083G>T p.R3028M (on ENST00000591111; = p.R2982M on NM_003319.4) | Missense Mutation (SNP) | VAF 275/458 reads (60%) | PolyPhen probably damaging (0.998); catalogued as COSV60353046; called by muse, mutect2, varscan2
- TUSC3 | c.196T>G p.F66V | Missense Mutation (SNP) | VAF 179/656 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV65879134, COSV65887519; called by muse, mutect2, varscan2
- TXNDC12 | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 77/315 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1217242438; called by muse, mutect2, varscan2
- ULK2 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 145/462 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs372735795; called by muse, mutect2, varscan2
- XRRA1 | c.2093G>A p.R698Q | Missense Mutation (SNP) | VAF 101/278 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs769038963; called by muse, mutect2, varscan2
- ZFP92 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 278/883 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs1556975120, COSV58598291; called by muse, mutect2, varscan2
- ZNF804B | c.2537G>T p.C846F | Missense Mutation (SNP) | VAF 153/370 reads (41%) | SIFT tolerated (0.73); PolyPhen benign (0.38); catalogued as COSV60814748; called by muse, mutect2, varscan2
- ARHGAP6 | c.377T>G p.L126R | Missense Mutation (SNP) | VAF 401/751 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- CARMIL3 | c.2155dup p.R719Pfs*19 | Frame Shift Ins (INS) | VAF 179/521 reads (34%) | called by mutect2, pindel, varscan2
- CERKL | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 264/451 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CH25H | c.421G>C p.V141L | Missense Mutation (SNP) | VAF 156/457 reads (34%) | SIFT tolerated (0.75); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CLIP4 | c.1972C>G p.L658V | Missense Mutation (SNP) | VAF 38/544 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CLOCK | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 20/272 reads (7%) | called by muse, mutect2
- COPS5 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 210/351 reads (60%) | SIFT tolerated (0.28); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ERBB2 | c.317A>G p.Q106R | Missense Mutation (SNP) | VAF 303/536 reads (57%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- ERICH3 | c.1535A>C p.K512T | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- ETNPPL | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 304/545 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EYS | c.2966A>C p.N989T | Missense Mutation (SNP) | VAF 137/283 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FGF2 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRMPD2 | c.2858T>C p.L953P | Missense Mutation (SNP) | VAF 18/272 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRXCR1 | c.697G>C p.V233L | Missense Mutation (SNP) | VAF 151/282 reads (54%) | SIFT tolerated (0.36); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- GTF2IRD2B | c.2567C>T p.T856M | Missense Mutation (SNP) | VAF 125/558 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HSPA5 | c.217dup p.E73Gfs*22 | Frame Shift Ins (INS) | VAF 265/683 reads (39%) | called by mutect2, pindel, varscan2
- ITGAM | c.154dup p.Q52Pfs*64 | Frame Shift Ins (INS) | VAF 131/450 reads (29%) | called by mutect2, pindel, varscan2
- KIAA0319L | c.2996G>A p.S999N | Missense Mutation (SNP) | VAF 92/334 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, varscan2
- KIF1B | c.2355G>T p.K785N (on ENST00000377086 / NM_001365952.1; = p.K739N on NM_015074.3) | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- LIMK1 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 52/947 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LINC02218 | c.554A>G p.K185R | Missense Mutation (SNP) | VAF 190/407 reads (47%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- LMNTD1 | c.494C>A p.S165Y | Missense Mutation (SNP) | VAF 26/420 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- LTBP2 | c.2091C>A p.C697* | Nonsense Mutation (SNP) | VAF 153/744 reads (21%) | called by muse, mutect2, varscan2
- MAOB | c.1549C>A p.L517I | Missense Mutation (SNP) | VAF 213/459 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MAPK3 | c.254C>T p.T85M | Missense Mutation (SNP) | VAF 294/540 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MUC16 | c.13844C>T p.T4615I | Missense Mutation (SNP) | VAF 34/570 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.065); called by muse, mutect2
- NKAIN2 | c.362C>A p.T121K | Missense Mutation (SNP) | VAF 279/508 reads (55%) | SIFT tolerated (0.95); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- NOX4 | c.1643G>T p.G548V | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NRAP | c.3223C>A p.Q1075K (on ENST00000359988 / NM_001322945.2; = p.Q1040K on NM_006175.4) | Missense Mutation (SNP) | VAF 156/329 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR5D13 | c.626A>C p.E209A | Missense Mutation (SNP) | VAF 29/419 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.768); called by muse, mutect2
- OR8H1 | c.815T>C p.V272A | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- PLXNA4 | c.5463G>T p.M1821I | Missense Mutation (SNP) | VAF 85/430 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- PPP1R16A | c.1021A>T p.S341C | Missense Mutation (SNP) | VAF 273/938 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- PPP4R3C | c.554T>G p.L185R | Missense Mutation (SNP) | VAF 86/263 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- RHOBTB3 | c.239A>G p.D80G | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RIMS2 | c.917A>G p.E306G (on ENST00000666250 / NM_001348490.2; = p.E114G on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 104/443 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- RIOX2 | c.812C>G p.T271S | Missense Mutation (SNP) | VAF 157/405 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RPS6KA1 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 101/339 reads (30%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RXFP1 | c.1511C>T p.T504I | Missense Mutation (SNP) | VAF 148/313 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SETD2 | c.7429G>A p.E2477K | Missense Mutation (SNP) | VAF 97/247 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- SLFN12L | c.938_939del p.A313Gfs*4 (on ENST00000260908 / NM_001363830.1; = p.A331Gfs*4 on NM_001195790.1) | Frame Shift Del (DEL) | VAF 76/323 reads (24%) | called by mutect2, pindel, varscan2
- SOX1 | c.1120C>A p.H374N | Missense Mutation (SNP) | VAF 307/518 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- STRAP | c.743A>G p.Y248C | Missense Mutation (SNP) | VAF 88/198 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TAF11L13 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 98/201 reads (49%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- TENM1 | c.1545G>T p.K515N | Missense Mutation (SNP) | VAF 121/356 reads (34%) | SIFT tolerated (0.76); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMCO4 | c.439G>T p.V147L | Missense Mutation (SNP) | VAF 202/410 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNRC18 | c.2261_2262insGG p.S754Rfs*21 | Frame Shift Ins (INS) | VAF 178/494 reads (36%) | called by pindel, varscan2
- TPRG1 | c.205A>G p.T69A | Missense Mutation (SNP) | VAF 120/276 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- VCP | c.1070T>A p.L357Q | Missense Mutation (SNP) | VAF 85/491 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VPS13B | c.8853G>T p.K2951N | Missense Mutation (SNP) | VAF 109/382 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZEB2 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 234/449 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.432G>A p.S144= | Silent (SNP) | VAF 285/623 reads (46%) | catalogued as rs139118990; called by muse, mutect2, varscan2
- ANKRD24 | c.2931C>T p.N977= | Silent (SNP) | VAF 251/672 reads (37%) | catalogued as rs1019103263; called by muse, mutect2, varscan2
- BCL11A | c.1974G>A p.S658= (on ENST00000335712 / NM_001365609.1; = p.S692= on NM_018014.4) | Silent (SNP) | VAF 170/585 reads (29%) | catalogued as rs146556401; called by muse, mutect2, varscan2
- C4orf54 | c.4998C>T p.A1666= | Silent (SNP) | VAF 182/341 reads (53%) | called by muse, mutect2, varscan2
- CAMSAP1 | c.2133C>T p.T711= | Silent (SNP) | VAF 240/592 reads (41%) | catalogued as rs186741880, COSV100409995; called by muse, mutect2, varscan2
- CD163L1 | c.2361G>A p.L787= | Silent (SNP) | VAF 126/272 reads (46%) | called by muse, mutect2, varscan2
- CHD7 | c.7086C>T p.S2362= | Silent (SNP) | VAF 209/755 reads (28%) | catalogued as rs757280832; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CPQ | c.468C>T p.F156= | Silent (SNP) | VAF 167/582 reads (29%) | catalogued as rs1237209399, COSV55162497; called by muse, mutect2, varscan2
- DCAF4L2 | c.483G>T p.A161= | Silent (SNP) | VAF 241/814 reads (30%) | catalogued as COSV60480151; called by muse, mutect2, varscan2
- DNAH5 | c.8716C>T p.L2906= | Silent (SNP) | VAF 122/389 reads (31%) | catalogued as COSV54210372; called by muse, mutect2, varscan2
- EPN2 | c.1140A>G p.P380= | Silent (SNP) | VAF 262/465 reads (56%) | catalogued as rs768002641; called by muse, mutect2, varscan2
- F8 | c.6708T>C p.N2236= | Silent (SNP) | VAF 24/359 reads (7%) | called by muse, mutect2
- FOXD4L4 | c.240G>A p.P80= | Silent (SNP) | VAF 90/1726 reads (5%) | called by muse, mutect2
- GPR15 | c.963G>A p.L321= | Silent (SNP) | VAF 206/442 reads (47%) | called by muse, mutect2, varscan2
- GSTM4 | c.222C>T p.N74= | Silent (SNP) | VAF 179/637 reads (28%) | catalogued as rs375225696; called by muse, mutect2, varscan2
- HERC2 | c.13449C>T p.S4483= | Silent (SNP) | VAF 169/561 reads (30%) | catalogued as rs764614115; called by muse, mutect2, varscan2
- HOXB8 | c.291C>T p.F97= | Silent (SNP) | VAF 404/720 reads (56%) | called by muse, varscan2
- IGHV2-26 | c.165G>A p.V55= | Silent (SNP) | VAF 184/1425 reads (13%) | catalogued as rs1237847762; called by muse, mutect2, varscan2
- LZTS3 | c.78C>T p.S26= | Silent (SNP) | VAF 185/940 reads (20%) | catalogued as rs3746701; called by muse, mutect2, varscan2
- MAP3K5 | c.3135G>A p.R1045= | Silent (SNP) | VAF 111/385 reads (29%) | called by muse, mutect2, varscan2
- MC3R | c.684C>T p.D228= | Silent (SNP) | VAF 338/754 reads (45%) | catalogued as COSV54765274; called by muse, mutect2, varscan2
- MYH7 | c.4641C>T p.A1547= | Silent (SNP) | VAF 130/321 reads (40%) | catalogued as rs376854724; called by muse, mutect2, varscan2
- NCKIPSD | c.1875G>A p.P625= | Silent (SNP) | VAF 228/643 reads (35%) | catalogued as rs550922203; called by muse, mutect2, varscan2
- NRG1 | c.9C>T p.S3= (on ENST00000523534; = p.S150= on NM_013962.2) | Silent (SNP) | VAF 115/810 reads (14%) | called by muse, mutect2, varscan2
- NSG1 | c.222G>A p.T74= | Silent (SNP) | VAF 253/460 reads (55%) | catalogued as rs779838685; called by muse, mutect2, varscan2
- PCDHA13 | c.123C>T p.H41= | Silent (SNP) | VAF 57/705 reads (8%) | called by muse, mutect2
- PDE3A | c.99G>A p.A33= | Silent (SNP) | VAF 363/837 reads (43%) | called by muse, mutect2, varscan2
- PGR | c.873C>T p.P291= | Silent (SNP) | VAF 260/763 reads (34%) | catalogued as COSV54795552; called by muse, mutect2, varscan2
- PIK3CG | c.1026C>T p.H342= | Silent (SNP) | VAF 243/508 reads (48%) | catalogued as rs539823993, COSV63253458; called by muse, mutect2, varscan2
- RYR3 | c.11673C>A p.G3891= (on ENST00000389232; = p.G3892= on NM_001036.6) | Silent (SNP) | VAF 97/193 reads (50%) | called by muse, mutect2, varscan2
- SALL2 | c.1554A>G p.E518= | Silent (SNP) | VAF 289/604 reads (48%) | called by muse, mutect2, varscan2
- SLC35D3 | c.579C>T p.I193= | Silent (SNP) | VAF 232/690 reads (34%) | catalogued as rs201285388; called by muse, mutect2, varscan2
- SLC4A1 | c.489C>T p.H163= | Silent (SNP) | VAF 106/337 reads (31%) | catalogued as rs149933181; called by muse, mutect2, varscan2
- SPACA1 | c.192G>A p.P64= | Silent (SNP) | VAF 25/360 reads (7%) | catalogued as rs754914513, COSV52761542; called by muse, mutect2
- TENM1 | c.816C>T p.I272= | Silent (SNP) | VAF 26/674 reads (4%) | catalogued as COSV64425201, COSV64436635; called by muse, mutect2
- TIAM1 | c.4521C>T p.D1507= | Silent (SNP) | VAF 281/610 reads (46%) | catalogued as rs1228855775; called by muse, mutect2, varscan2
- TMEM271 | c.141C>T p.A47= | Silent (SNP) | VAF 364/702 reads (52%) | called by muse, mutect2, varscan2
- ZFPM2 | c.2505G>A p.K835= | Silent (SNP) | VAF 201/718 reads (28%) | catalogued as COSV65874820; called by muse, mutect2, varscan2
- ZNF358 | c.915G>A p.A305= | Silent (SNP) | VAF 76/916 reads (8%) | catalogued as COSV51173830; called by muse, mutect2
- GABARAPL1 | c.288+119C>T | Intron (SNP) | VAF 140/357 reads (39%) | catalogued as rs1259130198; called by muse, mutect2, varscan2
- KIR3DX1 | n.1168C>T | RNA (SNP) | VAF 130/479 reads (27%) | catalogued as rs750116542; called by muse, mutect2, varscan2
- LINC00662 | n.687C>T | RNA (SNP) | VAF 150/353 reads (42%) | catalogued as rs768383838; called by muse, mutect2, varscan2
- MT3 | c.97+29G>A | Intron (SNP) | VAF 24/650 reads (4%) | catalogued as rs1419041366, COSV52365744; called by muse, mutect2
- MYL3 | chr3:46833947 G>A | 3'Flank (SNP) | VAF 438/987 reads (44%) | catalogued as rs868399479; called by muse, mutect2, varscan2
- TBXA2R | c.*24G>A | 3'UTR (SNP) | VAF 293/620 reads (47%) | catalogued as rs200736764; called by muse, mutect2, varscan2
